Somatic mutation profile of tumor specimen MMRF_1731_1_BM_CD138pos (aliquot MMRF_1731_1_BM_CD138pos_T1_KBS5U_L06421) from MMRF case MMRF_1731, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 50.9 years (18,588 days).
Specimen MMRF_1731_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 55553af9-571c-49a3-9a44-cb2a21c7243a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1731_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1731_1_PB_Whole_C3_KBS5U_L06469; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fc0cd66d-f52d-4215-981f-68c0fa30a163

The open-access MAF lists 72 somatic variants for this specimen: 27 protein-altering or splice-affecting, 7 silent, 38 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 26, Missense Mutation 21, Intron 9, Silent 7, Nonsense Mutation 3, 3'Flank 2, Frame Shift Del 2, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BICD2 | c.950C>T p.T317I | Missense Mutation (SNP) | VAF 70/117 reads (60%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as rs1345664005; called by muse, mutect2, varscan2
- EPHX3 | c.505C>T p.L169F | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1326353175; called by muse, mutect2, varscan2
- FAM83H | c.1894G>A p.V632I | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs371718430; called by muse, mutect2, varscan2
- FPR2 | c.274C>T p.P92S | Missense Mutation (SNP) | VAF 51/124 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs766221747, COSV60673878; called by muse, mutect2, varscan2
- GABRB3 | c.1178T>A p.I393K | Missense Mutation (SNP) | VAF 59/151 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.102); catalogued as COSV54664765; called by muse, mutect2, varscan2
- IGLV3-1 | c.314A>G p.Y105C | Missense Mutation (SNP) | VAF 58/146 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs185803370; called by muse, mutect2, varscan2
- LIMCH1 | c.607G>A p.D203N | Missense Mutation (SNP) | VAF 95/200 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs760768105, COSV58302319; called by muse, mutect2, varscan2
- NEO1 | c.4122del p.Y1375Mfs*16 | Frame Shift Del (DEL) | VAF 61/194 reads (31%) | catalogued as COSV99982378; called by mutect2, pindel, varscan2
- RRAD | c.631C>T p.R211C | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55336432; called by muse, mutect2, varscan2
- SNX14 | c.2425C>T p.H809Y (on ENST00000314673 / NM_001350535.1; = p.H756Y on NM_020468.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1220817629; called by muse, mutect2, varscan2
- ADGRD2 | c.2522-6C>A | Splice Region (SNP) | VAF 58/110 reads (53%) | called by muse, mutect2, varscan2
- CCHCR1 | c.925G>T p.E309* | Nonsense Mutation (SNP) | VAF 8/29 reads (28%) | called by muse, mutect2, varscan2
- COL11A2 | c.1019C>T p.P340L | Missense Mutation (SNP) | VAF 106/218 reads (49%) | SIFT tolerated (0.25); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- EYS | c.7651del p.Y2551Mfs*2 | Frame Shift Del (DEL) | VAF 80/235 reads (34%) | called by mutect2, pindel, varscan2
- FNDC1 | c.544C>A p.L182M | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- ITPR1 | c.3916A>G p.N1306D (on ENST00000354582; = p.N1291D on NM_002222.7) | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- KALRN | c.3869T>C p.L1290P | Missense Mutation (SNP) | VAF 84/191 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KDM7A | c.166G>A p.D56N | Missense Mutation (SNP) | VAF 10/149 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- LAMA1 | c.1897G>T p.E633* | Nonsense Mutation (SNP) | VAF 46/133 reads (35%) | called by muse, mutect2, varscan2
- LGI3 | c.1157G>A p.G386D | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MASTL | c.1805C>G p.S602* | Nonsense Mutation (SNP) | VAF 39/128 reads (30%) | called by muse, mutect2, varscan2
- MEX3B | c.1460C>T p.P487L | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- MYO1D | c.320G>C p.G107A | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MYO1F | c.3022C>A p.L1008I | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.407); called by muse, mutect2, varscan2
- PIWIL4 | c.1960A>G p.I654V | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT tolerated (0.94); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- PTPRQ | c.4061C>G p.S1354C (on ENST00000616559; = p.S1312C on NM_001145026.2) | Missense Mutation (SNP) | VAF 80/171 reads (47%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- SLC7A13 | c.1261C>A p.H421N | Missense Mutation (SNP) | VAF 111/365 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.233); called by muse, mutect2, varscan2
- ABCC12 | c.1809C>T p.L603= | Silent (SNP) | VAF 67/147 reads (46%) | catalogued as rs770598854, COSV60913554; called by muse, mutect2, varscan2
- CCND1 | c.186C>A p.T62= | Silent (SNP) | VAF 91/165 reads (55%) | called by muse, varscan2
- CDC37 | c.960C>T p.A320= | Silent (SNP) | VAF 43/108 reads (40%) | catalogued as rs763402340; called by muse, mutect2, varscan2
- FAM234B | c.762C>T p.N254= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as rs759389681, COSV52193770; called by muse, mutect2, varscan2
- NPTX2 | c.693C>T p.L231= | Silent (SNP) | VAF 56/179 reads (31%) | catalogued as COSV55719177; called by muse, mutect2, varscan2
- PCDHAC1 | c.747G>T p.G249= | Silent (SNP) | VAF 10/143 reads (7%) | catalogued as rs1563094908; called by muse, mutect2
- TRAM1L1 | c.1023T>G p.S341= | Silent (SNP) | VAF 125/279 reads (45%) | called by muse, mutect2, varscan2
- AC073348.1 | n.206A>T | RNA (SNP) | VAF 15/258 reads (6%) | called by muse, mutect2
- ACP5 | c.262-19C>G | Intron (SNP) | VAF 85/186 reads (46%) | called by muse, mutect2, varscan2
- ARID5B | c.*544C>T | 3'UTR (SNP) | VAF 8/34 reads (24%) | called by muse, mutect2, varscan2
- CACNA1G | c.*210A>G | 3'UTR (SNP) | VAF 21/60 reads (35%) | called by muse, mutect2, varscan2
- CARS1 | c.*140C>T | 3'UTR (SNP) | VAF 33/90 reads (37%) | catalogued as rs192795142; called by muse, mutect2, varscan2
- CCDC125 | c.*1548G>C | 3'UTR (SNP) | VAF 4/88 reads (5%) | catalogued as rs1412405746; called by muse, mutect2
- CCDC198 | c.*269T>C | 3'UTR (SNP) | VAF 37/87 reads (43%) | called by muse, mutect2, varscan2
- CCSER1 | c.2011-33882A>C | Intron (SNP) | VAF 25/55 reads (45%) | called by muse, mutect2, varscan2
- DIPK1B | c.199-863G>C | Intron (SNP) | VAF 32/143 reads (22%) | called by muse, mutect2, varscan2
- DPT | c.*1069T>G | 3'UTR (SNP) | VAF 23/59 reads (39%) | called by muse, mutect2
- ETS1 | chr11:128458812 A>G | 3'Flank (SNP) | VAF 38/61 reads (62%) | called by muse, mutect2, varscan2
- FBXO46 | c.*588G>A | 3'UTR (SNP) | VAF 4/23 reads (17%) | catalogued as rs1401483165; called by muse, mutect2, varscan2
- FLRT2 | c.*2080C>T | 3'UTR (SNP) | VAF 8/81 reads (10%) | called by muse, mutect2, varscan2
- GABRA2 | chr4:46249314 A>G | 3'Flank (SNP) | VAF 12/36 reads (33%) | called by muse, mutect2, varscan2
- H2AC20 | c.*9A>T | 3'UTR (SNP) | VAF 113/294 reads (38%) | called by muse, mutect2, varscan2
- HEPHL1 | c.*683T>G | 3'UTR (SNP) | VAF 37/70 reads (53%) | called by muse, mutect2, varscan2
- HGF | c.865+656dup | Intron (INS) | VAF 37/72 reads (51%) | called by mutect2, pindel, varscan2
- HIC2 | c.*3353G>T | 3'UTR (SNP) | VAF 36/68 reads (53%) | catalogued as COSV68042017; called by muse, mutect2, varscan2
- INTS3 | c.*817C>A | 3'UTR (SNP) | VAF 11/18 reads (61%) | called by muse, mutect2, varscan2
- KCNJ10 | c.*1195G>A | 3'UTR (SNP) | VAF 5/58 reads (9%) | catalogued as COSV63634694; called by muse, mutect2
- MGAT4A | c.*3822A>G | 3'UTR (SNP) | VAF 23/53 reads (43%) | called by muse, mutect2, varscan2
- NPTX2 | c.*91T>A | 3'UTR (SNP) | VAF 28/77 reads (36%) | called by muse, mutect2, varscan2
- PABPC3 | c.*673T>C | 3'UTR (SNP) | VAF 21/26 reads (81%) | called by muse, mutect2, varscan2
- PAPPA2 | c.2431+264dup | Intron (INS) | VAF 26/75 reads (35%) | called by mutect2, pindel, varscan2
- PCDHB5 | c.*18G>A | 3'UTR (SNP) | VAF 120/273 reads (44%) | catalogued as rs1299109959, COSV50649508; called by muse, mutect2, varscan2
- PI15 | c.*2681C>T | 3'UTR (SNP) | VAF 27/85 reads (32%) | catalogued as COSV99477996; called by muse, mutect2, varscan2
- PLPP6 | c.*97C>T | 3'UTR (SNP) | VAF 69/166 reads (42%) | called by muse, mutect2, varscan2
- RFX4 | c.994-18G>A | Intron (SNP) | VAF 34/78 reads (44%) | called by muse, mutect2, varscan2
- SLC10A7 | c.183+2599C>T | Intron (SNP) | VAF 4/70 reads (6%) | catalogued as rs1560985684; called by muse, mutect2
- STK11IP | c.987+79G>A | Intron (SNP) | VAF 3/35 reads (9%) | called by muse, mutect2
- TEDDM1 | c.*661A>G | 3'UTR (SNP) | VAF 29/77 reads (38%) | called by muse, mutect2, varscan2
- TENT4A | c.*74C>T | 3'UTR (SNP) | VAF 24/62 reads (39%) | catalogued as rs896598811; called by muse, mutect2, varscan2
- TKFC | c.1576-19C>G | Intron (SNP) | VAF 42/109 reads (39%) | called by muse, mutect2, varscan2
- TMEM30B | c.*2544C>T | 3'UTR (SNP) | VAF 25/40 reads (63%) | called by muse, mutect2, varscan2
- TP73 | c.*489T>C | 3'UTR (SNP) | VAF 95/265 reads (36%) | called by muse, mutect2, varscan2
- TRIM66 | c.*4223A>G | 3'UTR (SNP) | VAF 22/64 reads (34%) | catalogued as rs961650902; called by muse, mutect2, varscan2
- XKR7 | c.*166G>A | 3'UTR (SNP) | VAF 18/68 reads (26%) | catalogued as rs972150546, COSV73813277; called by muse, mutect2, varscan2
- ZNF396 | c.*2237T>G | 3'UTR (SNP) | VAF 29/71 reads (41%) | called by muse, mutect2, varscan2
